CMI case MBCproject_0095 — CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/d19c79b5-121e-46ac-9652-97bc6ec9fb00

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Age at diagnosis: 32.1 years (11,708 days).

Biospecimens (5 samples)
- Sample MBCproject_0095_SALIVA: Sample type: DNA; Tissue type: Normal; Specimen type: Saliva; Biospecimen anatomic site: Other.
- Sample MBCproject_0095_T1_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Liver; Preservation method: FFPE.
- Samples MBCproject_0095_T2_WES, MBCproject_0095_T3_RNA, MBCproject_0095_T3_WES (3 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
